FM case AD1187 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/0acbcd6f-51aa-4454-99ab-f1c7043925ee

Female, 61.5 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
